Gene-level copy-number profile of tumor specimen TCGA-36-1568-01A from TCGA case TCGA-36-1568, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 52.9 years (19,311 days).
Specimen TCGA-36-1568-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.d99f3cec-5a1f-451a-b6e2-2de44f57a4ae.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-36-1568-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0fd72239-d463-4e9b-bd3a-39df4d78eddb

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 10,846; copy number 2: 36,673; copy number 3: 10,570; copy number 4: 829; copy number 5: 68; copy number 6: 827.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-36-1568-01): tumor purity 0.81, ploidy 2.11, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr22:41,092,513–41,183,144, 4 genes (within-gene range 0–1): MIR1281, EP300, RNU6-375P, AL035658.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 895 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:158,456,952–159,232,659, 16 genes, copy number 5 (within-gene range 2–5): PKP4, RPL7AP22, PKP4-AS1, AC005042.1, AC005042.2, DAPL1, AC064843.1, OR7E89P, OR7E28P, OR7E90P, RNU2-21P, TANC1, BTF3L4P2, RNU6-580P, GSTM3P2, MIR6888.
- chr6:3,224,277–11,807,046, 165 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr8:99,796,615–145,066,685, 714 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 10,727. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
